Somatic mutation profile of tumor specimen C3N-05039-01 (aliquot CPT0375550007) from CPTAC case C3N-05039, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 74.0 years (27,030 days).
Specimen C3N-05039-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7632d18-4718-4684-b56c-36f6a3dad731.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-05039-31 (Blood Derived Normal), aliquot CPT0375610002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7bec9b88-055a-413d-b2f9-d79c2307481c

The open-access MAF lists 62 somatic variants for this specimen: 48 protein-altering or splice-affecting, 6 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 6, Intron 4, Nonsense Mutation 3, 3'UTR 2, 5'UTR 2, Splice Region 2, Frame Shift Del 2, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.393_395del p.N131del | In Frame Del (DEL) | VAF 161/242 reads (67%) | hotspot (GDC flag); catalogued as rs879254214; called by pindel, varscan2
- ABCB1 | c.2006G>A p.R669H | Missense Mutation (SNP) | VAF 46/355 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs146703713; called by muse, mutect2, varscan2
- ADAMTS9 | c.3479G>C p.C1160S | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55776837; called by muse, mutect2, varscan2
- ADGRF5 | c.3232C>T p.R1078C | Missense Mutation (SNP) | VAF 88/235 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.616); catalogued as rs1196481373, COSV51930188; called by muse, mutect2, varscan2
- CCDC50 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs575240044, COSV66668776; ClinVar: uncertain significance; called by muse, mutect2
- CISH | c.445C>T p.R149C (on ENST00000348721 / NM_145071.4; = p.R166C on NM_013324.6) | Missense Mutation (SNP) | VAF 120/347 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.315); catalogued as rs375441453; called by muse, mutect2, varscan2
- DEAF1 | c.1642G>A p.V548I | Missense Mutation (SNP) | VAF 16/455 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.274); catalogued as rs1472386316, COSV51563211; called by muse, mutect2
- FAM47C | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 29/253 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs781884172, COSV63723626; called by muse, mutect2, varscan2
- ITLN1 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 93/231 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as rs761053617; called by muse, mutect2, varscan2
- KEL | c.1963C>T p.R655W | Missense Mutation (SNP) | VAF 144/615 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs370938244, COSV62335275; called by muse, mutect2, varscan2
- KIF2B | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 101/257 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.811); catalogued as rs770787002, COSV52130448; called by muse, mutect2, varscan2
- MAGEB3 | c.360G>T p.Q120H | Missense Mutation (SNP) | VAF 45/65 reads (69%) | SIFT tolerated (0.26); PolyPhen benign (0.164); catalogued as COSV64397675; called by muse, mutect2, varscan2
- MUC16 | c.31011C>A p.F10337L | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.015); catalogued as COSV67467765; called by muse, mutect2, varscan2
- MUC16 | c.20617G>T p.D6873Y | Missense Mutation (SNP) | VAF 111/329 reads (34%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.452); catalogued as COSV101199803; called by muse, mutect2, varscan2
- MYO5B | c.2485C>T p.R829C | Missense Mutation (SNP) | VAF 293/779 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as rs375202395; called by muse, mutect2, varscan2
- MYOM3 | c.3586G>A p.G1196R | Missense Mutation (SNP) | VAF 67/236 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1352553590; called by muse, mutect2, varscan2
- OR51E1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs758137608, COSV101211577; called by muse, mutect2, varscan2
- PCDHB6 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 111/306 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1305694795, COSV50694689; called by muse, mutect2, varscan2
- PTEN | c.382A>G p.K128E | Missense Mutation (SNP) | VAF 166/307 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as HM090026, COSV64292814, COSV64297304; called by muse, mutect2, varscan2
- PTPRB | c.1585C>T p.R529* | Nonsense Mutation (SNP) | VAF 95/285 reads (33%) | catalogued as rs772938136, COSV54232377; called by muse, mutect2, varscan2
- RP1 | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 126/355 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55109741, COSV99606467; called by muse, mutect2, varscan2
- RYR2 | c.10361G>A p.R3454H | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1229045575, COSV63681265; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC35F3 | c.646G>A p.A216T (on ENST00000366617 / NM_001300845.1; = p.A285T on NM_173508.4) | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (1); PolyPhen probably damaging (0.958); catalogued as rs147645463; called by muse, mutect2, varscan2
- SLITRK4 | c.1934G>A p.R645H | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs997536820, COSV100567547, COSV62023284; called by muse, mutect2, varscan2
- SNX29 | c.2094C>G p.F698L | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1390010080; called by muse, mutect2
- TERT | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV57231088; called by muse, mutect2, varscan2
- TMC1 | c.1960A>T p.M654L | Missense Mutation (SNP) | VAF 263/426 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as CM020522; called by muse, mutect2, varscan2
- ZNF90 | c.1249_1253del p.I417Sfs*3 | Frame Shift Del (DEL) | VAF 69/271 reads (25%) | catalogued as rs1215943440; called by pindel, varscan2
- ADGRF4 | c.1444T>A p.F482I | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- DEPDC5 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 5/81 reads (6%) | called by muse, mutect2
- EDIL3 | c.1424dup p.C476Lfs*20 | Frame Shift Ins (INS) | VAF 137/480 reads (29%) | called by mutect2, pindel, varscan2
- ESPL1 | c.2364G>A p.K788= | Splice Region (SNP) | VAF 69/189 reads (37%) | called by muse, mutect2, varscan2
- IKZF5 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 14/157 reads (9%) | called by muse, mutect2
- LYST | c.11327T>C p.I3776T | Missense Mutation (SNP) | VAF 186/524 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- NLRP5 | c.869T>A p.I290N | Missense Mutation (SNP) | VAF 15/179 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- PKD1L1 | c.920A>C p.N307T | Missense Mutation (SNP) | VAF 116/481 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLXNB3 | c.3376C>G p.L1126V | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2
- POLR1F | c.338A>G p.H113R | Missense Mutation (SNP) | VAF 54/217 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RP1L1 | c.2717G>A p.G906E | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.219); called by muse, mutect2
- SCAF11 | c.3948_3949del p.P1317Sfs*22 | Frame Shift Del (DEL) | VAF 90/336 reads (27%) | called by pindel, varscan2
- SCGB2A2 | c.156C>A p.D52E | Missense Mutation (SNP) | VAF 86/311 reads (28%) | SIFT tolerated (0.79); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- SNX2 | c.158G>A p.S53N | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.988); called by muse, mutect2
- ST3GAL4 | c.102-8C>T | Splice Region (SNP) | VAF 57/142 reads (40%) | called by muse, mutect2, varscan2
- STEAP3 | c.114C>A p.D38E | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.108); called by muse, mutect2
- THY1 | c.8T>A p.L3Q | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- TULP1 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 24/426 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.058); called by muse, mutect2
- UBE4B | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF654 | c.68C>A p.S23Y | Missense Mutation (SNP) | VAF 15/207 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2
- ANKRD30B | c.939G>A p.T313= | Silent (SNP) | VAF 173/471 reads (37%) | catalogued as rs186852668, COSV62818607; called by muse, mutect2, varscan2
- KDM1A | c.21G>A p.A7= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs765582095, COSV63090741; called by mutect2, varscan2
- PALM | c.696G>A p.V232= | Silent (SNP) | VAF 74/373 reads (20%) | catalogued as COSV52771361; called by muse, mutect2, varscan2
- PTCHD4 | c.723C>T p.L241= | Silent (SNP) | VAF 120/296 reads (41%) | catalogued as rs267601057, COSV100260592; called by muse, mutect2, varscan2
- SH3RF2 | c.1245C>T p.D415= | Silent (SNP) | VAF 73/217 reads (34%) | catalogued as rs561869294, COSV63041358; called by muse, mutect2, varscan2
- TPRX1 | c.96C>T p.R32= | Silent (SNP) | VAF 56/159 reads (35%) | catalogued as rs1263469457; called by muse, mutect2, varscan2
- AADAC | c.-39T>A | 5'UTR (SNP) | VAF 17/285 reads (6%) | called by muse, mutect2
- CHIA | c.314+11T>C | Intron (SNP) | VAF 78/229 reads (34%) | called by muse, mutect2, varscan2
- FUBP1 | c.*1267G>A | 3'UTR (SNP) | VAF 41/258 reads (16%) | called by muse, mutect2, varscan2
- GDA | c.*2482C>T | 3'UTR (SNP) | VAF 57/89 reads (64%) | catalogued as rs758142317, COSV99429078; called by muse, mutect2, varscan2
- JPH3 | c.2167-1052G>A | Intron (SNP) | VAF 54/128 reads (42%) | catalogued as rs772493492; called by muse, mutect2, varscan2
- KIF2A | c.1647-1229G>C | Intron (SNP) | VAF 11/272 reads (4%) | called by muse, mutect2
- OSMR-AS1 | n.126+24045T>C | Intron (SNP) | VAF 11/19 reads (58%) | called by muse, mutect2, varscan2
- RPS27 | c.-11C>T | 5'UTR (SNP) | VAF 69/213 reads (32%) | catalogued as rs374881006; called by muse, mutect2, varscan2
